Somatic mutation profile of tumor specimen 0DYUZH from CCDI case PBCTHB, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Brain stem; Age at diagnosis: 3.8 years (1,382 days).
Specimen 0DYUZH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 474c4cd8-89ee-4bfd-8c8e-d1e76d4a7ee9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DYV1L (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d01bd78d-a8d2-4307-9693-5e9879dcf84b

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Silent 5, Nonsense Mutation 2, 5'UTR 1, In Frame Del 1, Intron 1, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACVR1 | c.983G>T p.G328V | Missense Mutation (SNP) | VAF 189/324 reads (58%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs387906589, CM091421, COSV55115990, COSV55115998; ClinVar: likely pathogenic / other; called by muse, mutect2, varscan2
- H3C2 | c.83A>T p.K28M | Missense Mutation (SNP) | VAF 88/214 reads (41%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.879); catalogued as COSV52517710, COSV52518111; called by muse, mutect2, varscan2
- ADGRG7 | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 26/146 reads (18%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.904); catalogued as rs773003928; called by muse, mutect2, varscan2
- BCOR | c.4200del p.P1401Rfs*83 (on ENST00000378444 / NM_001123385.2; = p.P1367Rfs*83 on NM_017745.6) | Frame Shift Del (DEL) | VAF 38/74 reads (51%) | catalogued as CD095798; called by mutect2, varscan2
- OR2C1 | c.785C>T p.P262L | Missense Mutation (SNP) | VAF 52/261 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs144009681, COSV59240731; called by muse, mutect2, varscan2
- PIK3R1 | c.1740C>A p.Y580* (on ENST00000521381 / NM_181523.3; = p.Y310* on NM_181504.4) | Nonsense Mutation (SNP) | VAF 18/152 reads (12%) | catalogued as COSV99141168; called by muse, varscan2
- SLC44A1 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 50/243 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs759502338, COSV66027133; called by muse, mutect2, varscan2
- THEG | c.773C>A p.A258E | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61074220; called by muse, mutect2, varscan2
- CNTN6 | c.1688T>G p.M563R | Missense Mutation (SNP) | VAF 18/133 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ELOA | c.966T>A p.S322R | Missense Mutation (SNP) | VAF 16/202 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.1); called by muse, mutect2
- PFAS | c.-79-5T>G | Splice Region (SNP) | VAF 23/72 reads (32%) | called by muse, mutect2, varscan2
- PIK3R1 | c.1209_1217del p.E403_N406delinsD (on ENST00000521381 / NM_181523.3; = p.E133_N136delinsD on NM_181504.4) | In Frame Del (DEL) | VAF 14/106 reads (13%) | called by mutect2, varscan2
- RGPD3 | c.1504G>A p.E502K | Missense Mutation (SNP) | VAF 58/435 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- TRAF3IP3 | c.790G>T p.G264* | Nonsense Mutation (SNP) | VAF 47/259 reads (18%) | called by muse, mutect2, varscan2
- ZNF518A | c.3328G>A p.V1110M | Missense Mutation (SNP) | VAF 39/234 reads (17%) | SIFT tolerated (0.81); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- BIVM-ERCC5 | c.2460A>G p.R820= | Silent (SNP) | VAF 52/223 reads (23%) | called by muse, mutect2, varscan2
- DSCAM | c.2430G>A p.T810= | Silent (SNP) | VAF 77/217 reads (35%) | catalogued as rs781279912; called by muse, mutect2, varscan2
- ITPR1 | c.4476C>T p.S1492= (on ENST00000354582; = p.S1477= on NM_002222.7) | Silent (SNP) | VAF 59/265 reads (22%) | catalogued as rs766557568; called by muse, mutect2, varscan2
- JUN | c.630C>T p.H210= | Silent (SNP) | VAF 12/296 reads (4%) | called by muse, mutect2
- TAF4B | c.1750C>T p.L584= | Silent (SNP) | VAF 11/92 reads (12%) | catalogued as rs766168221; called by muse, mutect2, varscan2
- LRP8 | c.-57C>A | 5'UTR (SNP) | VAF 3/23 reads (13%) | called by muse, varscan2
- USP54 | c.2678+48G>T | Intron (SNP) | VAF 11/85 reads (13%) | called by muse, mutect2
